Surgical pathology report (de-identified scan), TCGA case TCGA-BP-5001, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-5001-01A (Primary Tumor).

[page 1 of 2]
Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Ref. Source:

TCGA - BP - 5001

Clinical Diagnosis & History:

with right renal mass.

Specimens Submitted:

1: KIDNEY, RIGHT; PARTIAL NEPHRECTOMY

DIAGNOSIS:

1. KIDNEY, RIGHT; PARTIAL NEPHRECTOMY

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type

Fuhrman Nuclear Grade:

Nuclear grade II/IV

Tumor Size:

Greatest diameter is 4.1 cm.

Local Invasion (for renal cortical types):

Not identified

Renal Vein Invasion:

Not identified

Small vessel angiolymphatic invasion also not identified.

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Rare cortical scars

Adrenal Gland:

Not identified

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT1 Tumor <= 7.0 cm in greatest dimension limited to the kidney

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

[page 2 of 2]
[REDACTED]

SURGICAL PATHOLOGY REPORT

[REDACTED]

Gross Description:

[REDACTED]

1). The specimen is received fresh, labeled "right renal tumor". It consists of a 6.5 to 4.2 x 4.0 cm wedge shaped portion of kidney with a suture marking the deep margin. The margin is inked black and the specimen is serially sectioned to reveal a well-circumscribed yellow mass measuring 4.1 x 4.0 x 3.5 cm. The clearance from the resection margin is 0.1 cm. A representative section of the nearest margin is submitted for frozen section diagnosis. Representatively submitted. Portions of the tumor are submitted for TPS.

Summary of sections:

FSC - frozen section control

T - tumor

M - margin

RS - representative sections

Summary of Sections:

Part 1: KIDNEY, RIGHT; PARTIAL NEPHRECTOMY [REDACTED]

Block	Sect. Site	PCs
1	fsc	1
3	m	3
2	rs	2
3	t	3

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. FROZEN SECTION DIAGNOSIS: RENAL CORTICAL NEOPLASM. MARGINS (INKED) ARE FREE OF TUMOR.
[REDACTED] PERMANENT DIAGNOSIS: SAME
- [REDACTED]

Source: NCI Genomic Data Commons file 689b011a-7c37-4ae3-9050-e03505a38a08 (TCGA-BP-5001.ABB12726-85B5-4C11-B497-9BEA22DD6A43.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).